Somatic mutation profile of tumor specimen TCGA-R8-A6YH-01A (aliquot TCGA-R8-A6YH-01A-21D-A32B-08) from TCGA case TCGA-R8-A6YH, project TCGA-LGG (Brain Lower Grade Glioma).
Specimen TCGA-R8-A6YH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af74add9-038e-4e6c-aa51-9a6162e99d5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R8-A6YH-10B (Blood Derived Normal), aliquot TCGA-R8-A6YH-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/683546ab-f956-42cb-8220-2d57deac5353

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.823T>C p.C275R | Missense Mutation (SNP) | VAF 21/23 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519983, COSV52700773, COSV52771673; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATRX | c.3897dup p.K1300Efs*9 | Frame Shift Ins (INS) | VAF 31/48 reads (65%) | catalogued as COSV64871730; called by mutect2, pindel, varscan2
- CTSA | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs375345060; called by muse, mutect2, varscan2
- ZNF581 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs1437803660; called by mutect2, varscan2
- KRTAP13-1 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 76/91 reads (84%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MOAP1 | c.611G>C p.R204T | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- DNAH17 | c.2754G>A p.V918= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- FBXO15 | c.1428C>T p.H476= | Silent (SNP) | VAF 93/192 reads (48%) | catalogued as rs772583557; called by muse, mutect2, varscan2
- ROCK1 | c.2784A>G p.R928= | Silent (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- SYCP2 | c.1911A>G p.G637= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
